Gene-level copy-number profile of tumor specimen TCGA-55-7910-01A from TCGA case TCGA-55-7910, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.1 years (18,289 days).
Specimen TCGA-55-7910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6d0f0ac9-4921-4ad7-b106-f3daa92e0ee9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7910-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc9841c5-6129-4426-a5be-5387912ccf9e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 859; copy number 2: 12,741; copy number 3: 18,168; copy number 4: 14,497; copy number 5: 11,592; copy number 6: 369; copy number 7: 590; copy number 8: 445; copy number 9: 326; copy number 10: 2; copy number 11: 9; copy number 13: 3; copy number 15: 64; copy number 19: 8; copy number 24: 21; copy number 28: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7910-01A-11D-2166-01): tumor purity 0.58, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,867,027–10,361,045, 22 genes: AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598.
- chr12:10,407,382–12,211,084, 60 genes (within-gene range 0–3): KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,253 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,751,443–151,928,175, 1 gene, copy number 7 (within-gene range 4–7): AADACL2-AS1.
- chr3:151,797,047–173,336,965, 303 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:174,438,573–176,114,537, 18 genes, copy number 7: NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr5:3,452,816–13,638,381, 164 genes, copy number 7–9 (broad region; genes not listed).
- chr5:17,306,381–26,013,025, 114 genes, copy number 7–8 (broad region; genes not listed).
- chr5:40,240,167–43,707,405, 75 genes, copy number 7 (broad region; genes not listed).
- chr12:6,556,886–8,175,320, 101 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 2 genes, copy number 8 (within-gene range 4–8): SOX5, AC087260.1.
- chr12:25,409,307–25,648,579, 1 gene, copy number 7 (within-gene range 4–7): LMNTD1.
- chr12:25,585,994–26,966,650, 26 genes, copy number 7 (within-gene range 3–7): AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2.
- chr12:32,790,755–33,576,200, 10 genes, copy number 8: PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P.
- chr12:40,978,744–41,574,745, 2 genes, copy number 10 (within-gene range 4–10): AC015540.1, PDZRN4.
- chr12:46,682,071–47,279,021, 11 genes, copy number 8: MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4.
- chr12:47,661,249–48,191,207, 37 genes, copy number 9: RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1, PFKM, MIR6505, ASB8, AC074029.3, AC074029.2, PHBP18, AC074029.1, CCDC184, AC074029.4.
- chr12:48,202,083–48,203,387, 1 gene, copy number 9: OR10AD1.
- chr14:24,505,353–26,598,033, 19 genes, copy number 7–13: CMA1, CTSG, AL136018.1, GZMH, GZMB, STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1.
- chr14:27,258,717–31,488,039, 63 genes, copy number 8 (broad region; genes not listed).
- chr14:32,074,946–40,390,547, 138 genes, copy number 11–28 (broad region; genes not listed).
- chr20:43,063,326–44,842,539, 53 genes, copy number 9: RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2.
- chr20:47,656,348–52,890,386, 112 genes, copy number 9 (broad region; genes not listed).
- chr20:54,859,688–55,075,140, 2 genes, copy number 9: RNU4ATAC7P, RPL12P4.

Autosomal genes at a single copy (total copy number 1): 859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
